Surgical pathology report (de-identified scan), TCGA case TCGA-UY-A9PB, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UY-A9PB-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED] Accession #: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED] Service Date: [REDACTED]
DOB: [REDACTED] Sex: Male Received: [REDACTED]
Soc. Sec. #: [REDACTED] Location: [REDACTED] Client: [REDACTED]
Physician(s): [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

- ICD-O-3*
Carcinoma, urothelial NOS
Site Bladder, lateral wall
8/20/13
67.2
10/30/14
- A. Right ureter, biopsy: No evidence of carcinoma.
- B. Left ureter, biopsy: No evidence of carcinoma; see comment.
- C. Urinary bladder, prostate, right and left seminal vesicles, cystoprostatectomy:
- Urinary bladder: Urothelial carcinoma, high grade, 4.2 cm, involving perivesicle tissue; see comment.
- Prostate: Benign prostatic tissue.
- Right and left seminal vesicles: No significant pathologic abnormality.
- D. Lymph nodes, right pelvic, dissection: No tumor seen in 17 lymph nodes (0/17).
- E. Lymph nodes, left pelvic, dissection: No tumor seen in 12 lymph nodes (0/12).
- F. Left ureter, biopsy: No evidence of carcinoma; see comment.
- G. Right ureter, biopsy: No evidence of carcinoma; see comment.

COMMENT:

On slide B1 a few degenerating atypical cells are present. These cells are not present in frozen section slides. The differential diagnosis includes degenerating umbrella cells versus floater.

Deeper level sections were performed and evaluated on block G1 to confirm the diagnosis.

Bladder Tumor Synoptic Comment

- **Tumor type:** Urothelial (transitional cell) carcinoma.
- **Tumor grade:** High grade.
- **Tumor size:** 4.2 cm.

[page 2 of 4]
-
- **Extent of tumor in bladder:** Invasion through muscularis propria into perivesical tissue.
- **Lymphatic/vascular invasion:** None.
- **Epithelial abnormalities in bladder:** Carcinoma in situ.
- **Extension of tumor into adjacent organs:** None (tumor is seen growing toward prostate, but the prostate is not involved).
- **Margins:**
- **Urethral margin:** Carcinoma in situ (best demonstrated in frozen section slides).
- **Right ureter margin:** Negative.
- **Left ureter margin:** Negative.
- **Perivesical margin:** Negative.
- The status of the edges of the main specimen (Part C) are reported above. Additional parts (Parts A, B, F, G) are submitted by the surgeon as left and right ureter biopsies. Therefore, evaluation of the true surgical margin requires clinical correlation.
- **Lymph node status:** Negative.
- Total number of nodes examined: 29 (Parts D and E).
- **Other pathologic findings in bladder:** None.
- **AJCC/UICC stage:** pT3aN0MX.

Dr. [REDACTED] has reviewed B1 along with the frozen section slides, C3, G1 with levels and F1 and concurs.

Specimen(s) Received

A: Right Ureter, biopsy (FS)
B: Left Ureter, biopsy (FS)
C: Bladder and prostate (FS)
D: Lymph node, right pelvic
E: Lymph node, left pelvic
F: Ureter, left
G: Ureter, right

Intraoperative Diagnosis

FS1 (A) Right ureter, biopsy: No carcinoma. [REDACTED]

FS2 (B) Left ureter, biopsy: No carcinoma. ([REDACTED])

FS3 (C) Bladder and prostate, cystoprostatectomy: Atypical urothelium consistent with carcinoma in situ and single focus suspicious for superficially invasive carcinoma. [REDACTED]

Clinical History

The patient is a [REDACTED]-year-old man who developed gross hematuria in [REDACTED]. Cystoscopy and CT showed a right-sided bladder mass. TURBT ([REDACTED]) showed high-grade muscle invasive urothelial carcinoma of the bladder. He undergoes radical cystoprostatectomy.

Gross Description

The specimen is received in seven parts, each labeled with the patient's name and medical record number. Parts A-C are received fresh. Parts D-G are received in formalin.

Part A, labeled "right ureter," consists of a single unoriented pink fragment of soft tissue measuring 1.2 x 1.1 x 0.3 cm. It is entirely submitted for frozen section diagnosis 1, with the frozen section remnant submitted in cassette A1.

Part B, labeled "left ureter," consists of a single unoriented pink fragment of soft tissue measuring 1 x 1 x 0.3 cm. It is entirely frozen for frozen section diagnosis 2, with the frozen section remnant submitted in cassette B1.

[page 3 of 4]
Part C is additionally labeled "bladder/prostate," and consists of a single unoriented urinary bladder and prostate specimen weighing 346 grams and measuring 21.6 x 10 x 5.2 cm. The urinary bladder measures 7.5 x 7 x 6.2 cm with the attached anterior/superior fatty tissue measuring 10 x 8.5 x 3.8 cm.

The prostate measures 4.2 cm medial-lateral x 3 cm anterior-posterior x 2.7 cm superior-inferior. The serosal surface is mostly smooth and glistening without grossly obvious lesions. The ureteral margins are flush with the surrounding tissue (i.e., no appreciable length). The left ureter measures 0.6 cm in average diameter with a 0.2 cm wall thickness; the right ureter measures 0.5 cm in average diameter with a 0.1 cm to 0.2 cm wall thickness. The right anterior surface is inked green; the left anterior surface is inked blue; the posterior surface is inked black. The urethral margin is removed and submitted for frozen section diagnosis 3, with the frozen section remnant submitted in cassette C1. The urinary bladder and prostate are opened anteriorly to show a large red-tan ulcerated and necrotic mass occupying almost the entire right lateral bladder wall, measuring 4.2 x 3 cm. The left ureter is patent to probing; however, the right ureter cannot be probed due to blockage by the mass. Upon serial sectioning, the mass abuts the green inked margin (right anterior) with a maximum thickness of 1.8 cm. The mass appears to invade the muscularis propria with extension into the perivesical soft tissue. The mass is 0.7 cm to the black inked margin (posterior) and 2.7 cm to the blue inked margin (left anterior). The mass also appears to extend to and involve the base of the prostate. Serial sectioning of the prostate reveals mostly firm/rubbery porous tissue with punctate orange-brown gritty material scattered throughout. The base of the prostate appears to be involved by the urinary bladder mass; however, no other discrete lesions or masses/nodules are identified in the prostate. Representative sections are submitted as follows:

Cassette C1:	Urethral margin, en face (frozen section remnant).
Cassette C2:	Right ureter margin, en face.
Cassette C3:	Left ureter margin, en face.
Cassettes C4-C5:	Mass, closest to green inked margin (right anterior).
Cassette C6:	Mass, closest to black inked margin (posterior).
Cassette C7:	Mass and adjacent uninvolved mucosa.
Cassette C8:	Mass and prostate.
Cassette C9:	Uninvolved mucosa, dome.
Cassette C10:	Uninvolved mucosa, trigone (adjacent to left ureteral orifice).
Cassette C11:	Uninvolved mucosa, left lateral wall.
Cassette C12:	Prostate, right apex.
Cassette C13:	Prostate, right mid.
Cassette C14:	Prostate, right base, including seminal vesicle.
Cassette C15:	Prostate, left apex.
Cassette C16:	Prostate, left mid.
Cassette C17:	Prostate, left base, including seminal vesicle.
Cassette C18:	Four candidate lymph nodes, submitted whole.
Cassettes C19-C20:	Representative sections of perivesical fat.

Part D is additionally labeled "right pelvic lymph node." It consists of multiple soft, irregular pieces of tan-brown-yellow, fatty tissue measuring 10.1 x 7.5 x 2.2 cm in aggregate. Eighteen candidate lymph nodes are found ranging in size from 0.3 cm to 5.3 cm in greatest dimension. The candidate lymph nodes are submitted as follows:

Cassette D1:	Eight nodes.
Cassette D2:	Five nodes.
Cassette D3:	Two nodes, one node inked and bisected.
Cassettes D4-D5:	One node bisected.
Cassettes D6:	One node bisected.
Cassettes D8-D10:	One node bisected along the short axis as well as the long axis.

The remaining fatty tissue is returned to the container.

Part E is additionally labeled "left pelvic lymph node." It consists of multiple soft, irregular pieces of tan-brown-yellow, fatty tissue measuring 9.9 x 6.3 x 2.5 cm in aggregate. Fourteen candidate lymph nodes are found ranging in size from 0.3 cm to 5.2 cm. The candidate lymph nodes are submitted as follows:

Cassette E1:	Six nodes.
Cassette E2:	Four nodes.

[page 4 of 4]
Cassette E3: One node.
Cassette E4: One node bisected.
Cassettes E5-E6: One node bisected.
Cassettes E7-E9: One node serially sectioned.
The remaining fatty tissue is returned to the container.

Part F is additionally labeled "left ureter." It consists of a single soft, unoriented, tubular piece of off-white tissue with attached tan-brown, fibrofatty tissue measuring 2.5 x 1.3 x 0.2 cm. The tubular piece measures 0.5 cm in length and 0.5 cm in diameter. The lumen measures 0.1 cm. The specimen is entirely submitted in cassette F1.

Part G is additionally labeled "right ureter." It consists of a single soft, unoriented, tubular piece of off white-brown tissue measuring 0.9 cm in length and 0.7 cm in diameter. The lumen measures 0.2 cm. The specimen is entirely submitted in cassette G1.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Pathology Resident

Pathologist
Electronically signed out on

Source: NCI Genomic Data Commons file a234e995-2b2f-40d3-a103-7141e0d9b6f2 (TCGA-UY-A9PB.1CCAA482-BC52-4F00-89E4-31D0D9BBEAF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).